Somatic mutation profile of tumor specimen ALCH-ABMP-TTP1-A (aliquot ALCH-ABMP-TTP1-A-1-0-D-A488-36) from ALCHEMIST case ALCH-ABMP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 60.3 years (22,038 days).
Specimen ALCH-ABMP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c44bbf1-dd0b-4813-b988-ece7aa204c50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABMP-NB1-A (Blood Derived Normal), aliquot ALCH-ABMP-NB1-A-1-0-D-A488-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75763216-d27e-4cb7-8ef1-6a28c1c1d564

The open-access MAF lists 47 somatic variants for this specimen: 31 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 13, In Frame Del 1, Nonsense Mutation 1, RNA 1, Intron 1, Splice Region 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 119/556 reads (21%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- ABCA12 | c.1816G>A p.D606N (on ENST00000272895 / NM_173076.3; = p.D288N on NM_015657.3) | Missense Mutation (SNP) | VAF 75/381 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs957187113; called by muse, mutect2, varscan2
- CRISP1 | c.698C>A p.T233K | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.129); catalogued as COSV100236530; called by muse, mutect2, varscan2
- EHBP1 | c.3272G>C p.R1091P | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50427817; called by muse, varscan2
- F2 | c.788G>T p.R263L | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM114983, COSV61315012; called by muse, mutect2
- FPR2 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 15/290 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs866581731, COSV60672039; called by muse, mutect2
- FUT7 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs377550865; called by muse, mutect2, varscan2
- HSCB | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as COSV53262146; called by muse, mutect2, varscan2
- REST | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as rs923771558; called by muse, mutect2, varscan2
- TBC1D8B | c.2563C>T p.H855Y | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52177482; called by muse, mutect2, varscan2
- USP53 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1169673473; called by muse, mutect2
- ABCA8 | c.2171A>G p.D724G | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ABRAXAS2 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ANKRD23 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- BHMT | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CERKL | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CHRNB2 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 52/500 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNP | c.761C>A p.T254N | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- FOXK1 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- GLP2R | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1109 | c.8002G>T p.V2668L | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- KRR1 | c.123G>C p.K41N | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KRTDAP | c.247del p.D83Mfs*6 | Frame Shift Del (DEL) | VAF 24/152 reads (16%) | called by mutect2, pindel, varscan2
- LPA | c.3319G>A p.D1107N | Missense Mutation (SNP) | VAF 53/348 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- LRRTM1 | c.1304T>A p.L435H | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MGAM2 | c.5503A>G p.N1835D | Missense Mutation (SNP) | VAF 27/332 reads (8%) | SIFT tolerated, low confidence (0.46); called by muse, mutect2
- MKS1 | c.1096-7T>C | Splice Region (SNP) | VAF 73/482 reads (15%) | called by muse, mutect2, varscan2
- TRIM49C | c.1280A>C p.Q427P | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- TRPV5 | c.648C>A p.Y216* | Nonsense Mutation (SNP) | VAF 51/334 reads (15%) | called by muse, mutect2, varscan2
- ZEB2 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 28/437 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- ZNF292 | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 49/314 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ADCY2 | c.1575C>T p.T525= | Silent (SNP) | VAF 8/41 reads (20%) | called by muse, varscan2
- ANGPT2 | c.1452C>T p.L484= | Silent (SNP) | VAF 40/204 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP17 | c.468C>T p.N156= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as rs774847731; called by muse, mutect2
- DCAF15 | c.735C>G p.L245= | Silent (SNP) | VAF 30/240 reads (13%) | called by muse, mutect2, varscan2
- FAM83H | c.2163C>T p.P721= | Silent (SNP) | VAF 12/335 reads (4%) | catalogued as rs577110382; called by muse, mutect2
- HLCS | c.591C>G p.L197= | Silent (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- KRTAP2-4 | c.246G>A p.S82= | Silent (SNP) | VAF 14/167 reads (8%) | called by muse, mutect2, varscan2
- LRRTM1 | c.1302C>A p.A434= | Silent (SNP) | VAF 20/130 reads (15%) | called by muse, mutect2
- MS4A18 | c.354G>A p.L118= | Silent (SNP) | VAF 24/210 reads (11%) | called by muse, mutect2, varscan2
- OR2A14 | c.750C>T p.F250= | Silent (SNP) | VAF 19/398 reads (5%) | called by muse, mutect2
- PCDH17 | c.240C>T p.D80= | Silent (SNP) | VAF 22/190 reads (12%) | catalogued as rs368305031; called by muse, mutect2, varscan2
- PTGIR | c.546C>T p.A182= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs201046779, COSV52191755; called by muse, mutect2, varscan2
- TBC1D9B | c.2373G>A p.L791= | Silent (SNP) | VAF 19/242 reads (8%) | called by muse, mutect2
- ATXN2 | c.2038+17C>T | Intron (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- OR10V2P | n.228C>T | RNA (SNP) | VAF 14/121 reads (12%) | catalogued as rs939999902; called by muse, mutect2, varscan2
- TYMP | c.*1A>C | 3'UTR (SNP) | VAF 56/390 reads (14%) | called by muse, mutect2, varscan2
